Surgical pathology report (de-identified scan), TCGA case TCGA-M9-A5M8, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-M9-A5M8-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Adenocarcinoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Esophagus (involves GEJ)*
Tumour Size (cm)	5.5
Histology	Adenocarcinoma
Grade/Differentiation	II
Pathological T	T3
Pathological N	N0
Clinical M	M0
Histology Comments	*Tumour midpoint is in distal esophagus

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3

Adenocarcinoma NOS 8140/3

Path. Site Esophagus NOS C15.9

C&CF Site Esophagus, distal third C15.5
JW 2/11/13

Source: NCI Genomic Data Commons file 8e8b7750-3541-4f88-a91c-e7431e13f6fb (TCGA-M9-A5M8.F166E07E-53FF-464E-A107-315F64F5FF7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).